TCGA case TCGA-QR-A6GU — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/be7d999b-9725-4bf0-b337-cdc3ed55f05f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Alive.

Diagnoses (5)
1. Pheochromocytoma, NOS (the primary disease): ICD-O-3 morphology code: 8700/0; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 31.7 years (11,592 days); Year of diagnosis: 2008; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,791 days (4.9 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 25.0 years (9,145 days); Days to diagnosis: -2,447 days (-6.7 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,447 days (-6.7 years); Treatment anatomic sites: Neck.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 25.0 years (9,145 days); Days to diagnosis: -2,447 days (-6.7 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,629 days (-4.5 years); Treatment anatomic sites: Neck.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 26.1 years (9,540 days); Days to diagnosis: -2,052 days (-5.6 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,994 days (-5.5 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -317 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.
5. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 31.3 years (11,428 days); Days to diagnosis: -164 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 6 days; Treatment anatomic sites: Adrenal.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 1,791 days (4.9 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A6GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-QR-A6GU-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A6GU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A6GU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: Right glomus jugulare tumor, carotid body tumor; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Pheochromocytoma; Ct scan preop results: Yes.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Neck; Other malignancy histological type: paraganglioma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: resection of L neck mass.
- Other malignancy form 2, Surgery: Other malignancy surgery type: resection of R carotid body tumor.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: jugular foramen; Other malignancy histological type: paraganglioma.
- Other malignancy form 3, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.
- Other malignancy form 4: Malignancy type: Synchronous Malignancy; Other malignancy histological type: pheochromocytoma.
- Other malignancy form 4, Surgery: Other malignancy surgery type: adrenalectomy; Days from index date to other malignancy surgery: 6.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,791 days; disease-specific survival: no event (censored), 1,791 days; disease-free interval: no event (censored), 1,791 days; progression-free interval: no event (censored), 1,791 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QR-A6GU-01A-11D-A35C-01): tumor purity 0.68, ploidy 3.82, whole-genome doublings 1.
